Surgical pathology report (de-identified scan), TCGA case TCGA-94-A4VJ, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Emory, specimen TCGA-94-A4VJ-01A (Primary Tumor).

[page 1 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date:
Document Status: Auth (Verified)
Document Title: Histology
Performed By:
Verified By:
Encounter info:

* Final Report *

APRPT (Verified)

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

DOB:

Gender: F

Acc #:

Pulmonary Big

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. LYMPH NODE, 4R, EXCISION, A1FS:

- ONE LYMPH NODE NEGATIVE FOR CARCINOMA (0/1).

B. LYMPH NODE, #7, EXCISION, B1FS:

- ONE LYMPH NODE NEGATIVE FOR CARCINOMA (0/1).

C. LYMPH NODE, 4L, EXCISION, C1FS:

- ONE LYMPH NODE NEGATIVE FOR CARCINOMA (0/1).

D. LUNG, LEFT, PNEUMONECTOMY, D1FS:

- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 2.7 X 2.5 X 1.5.
- BRONCHIAL AND VASCULAR MARGINS NEGATIVE FOR CARCINOMA.
- FOCAL BRONCHIOLECTASIS.
- FIVE HILAR LYMPH NODES NEGATIVE FOR CARCINOMA (0/5).

1CD-0-3

carcinoma, squamous cell 8070/3

Site: bronchus, NOS C34.9

hw
10/25/12

[page 2 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

- SEE STAGING SUMMARY.

E. LYMPH NODE, #9, EXCISION:

- FOUR LYMPH NODES NEGATIVE FOR CARCINOMA (0/4).

F. LYMPH NODE, #7, EXCISION:

- ONE LYMPH NODE NEGATIVE FOR CARCINOMA (0/1).

G. LYMPH NODE, 10L, EXCISION:

- FIVE LYMPH NODES NEGATIVE FOR CARCINOMA (0/5).

H. LYMPH NODE, #6, EXCISION:

- THREE LYMPH NODES NEGATIVE FOR CARCINOMA (0/3).

I. LYMPH NODE, #5, EXCISION:

- ONE LYMPH NODE NEGATIVE FOR CARCINOMA (0/1).

Assisted by:

Synoptic Worksheet

D. Left lung, check bronchial margin:

Specimen:	Lung
Procedure:	Pneumonectomy
Specimen Integrity:	Intact
Specimen Laterality:	Left
Tumor Site:	Other: left mainstem bronchus
Tumor Focality:	Unifocal
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G2: Moderately differentiated
Tumor Size:	Greatest dimension: 2.7 cm
	Additional dimension: 2.5 cm
	Additional dimension: 1.5 cm
Visceral Pleura Invasion:	Not identified
Tumor Extension:	Not applicable
Bronchial Margin:	Uninvolved by invasive carcinoma
	Squamous cell carcinoma in situ (CIS) not identified at bronchial margin
Vascular Margin:	Uninvolved by invasive carcinoma
Parenchymal Margin:	Not applicable

[page 3 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Not applicable
Other Attached Tissue Margin:	Not applicable
All Margins Uninvolved By Invasive Carcinoma:	Distance of invasive carcinoma from closest margin: 0.6 mm Margin closest to invasive carcinoma:: vascular
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT1b: Tumor greater than 2 cm, but 3 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus)
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Nodes examined: 22 Nodes involved: 0
Distant Metastasis (pM):	Not applicable

Clinical History

Lung carcinoma. Bronch, mid, lymph node dissection, left thoracotomy, left pneumonectomy.

Specimen(s) Received

A: 4R lymph node
B: #7 lymph node
C: 4L lymph node
D: Left lung, check bronchial margin
E: #9 lymph node
F: #7 lymph node
G: 10L lymph node
H: #6 lymph node
I: #5 lymph node

Gross Description

Nine specimens are received; each is labeled with the patient's name and medical record number.

Specimen A is received for intraoperative consultation, and is labeled as "4R lymph node." It consists of multiple portions of grey-black soft tissue fragments measuring 2.0 x 1.5 x 0.6 cm in aggregate. The specimen is submitted entirely for frozen section diagnosis, then transferred to cassette "A1FS." Dictated by

Specimen B is received for intraoperative consultation and is labeled "#7 lymph node." It consists of multiple grey-black soft tissue fragments measuring in aggregate, 1.0 x 0.9 x 0.2 cm. The specimen is submitted entirely for frozen section diagnosis in cassette "B1FS." Dictated by

[page 4 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Specimen C is received for intraoperative consultation and is labeled "4L" It consists of multiple grey-black soft tissue fragments measuring in aggregate, 1.2 x 1.0 x 0.3 cm. The specimen is submitted entirely for frozen section diagnosis in cassette "C1FS." Dictated by

Specimen D is received fresh in a container labeled with the patient's name, medical record number and "left lung FS, check bronchial margin." The specimen consists of the left lung measuring 29.0 x 17.0 x 5.0 cm and weighing 350 grams. The pleural surface is smooth, red-pink with no other abnormalities. The hilar lymph nodes are slightly enlarged, the largest measuring 2.2 cm in greatest dimension. The bronchial margin shaved off and is submitted entirely for frozen section diagnosis in cassette "D1FS."

In the left main bronchus, there is a 2.7 x 2.5 x 1.5 cm mass abutting the pulmonary vasculature. Focal areas of mucous are also noted within airways in the left upper lobe and adjacent to the tumor. The cut surface of the tumor is grey-yellow and smooth with focal areas of hemorrhage. The tumor is 1.1 cm from the bronchial edge and 0.6 cm from the vascular margin and within 0.1 cm of the visceral pleura. No other lesions or masses are noted. Cassettes are submitted as follows: Dictated by

Specimen E is received labeled "#9 lymph node" and consists of four tissues from 1.0 x 0.5 x 0.2 cm up to 1.5 x 1.1 x 0.5 cm. Sectioning reveals four purple and black lymph nodes from 0.3 x 0.2 x 0.1 cm up to 1.3 x 0.8 x 0.4 cm. The node are submitted entirely in cassettes "E1" through "E4" as follows: Dictated by

Specimen F is received labeled "#7 lymph node" and consists of a black and red possible lymph node from 0.6 x 0.3 x 0.2 cm up to 2.2 x 1.5 x 0.8 cm. The specimen is submitted entirely in cassettes "F1" through "F5" as follows: Dictated by

Specimen G is received labeled "10L lymph node" and consists of five black possible lymph nodes from 0.4 x 0.2 x 0.1 cm up to 1.4 x 1.0 x 0.2 cm. These possible nodes are submitted in cassettes "G1" through "G3" as follows: Dictated by

Specimen H is received labeled "#6 lymph node" and consists of three possible lymph nodes from 1.1 x 0.6 x 0.3 cm up to 3.0 x 3.0 x 1.3 cm. The cut surface of each possible node is marked anthracotic pigment. The specimen is submitted entirely in cassettes "H1" through "H5" as follows: Dictated by

Specimen I is received labeled "#5 lymph node" and consists of a purple and black lymph node, 1.3 cm in greatest dimension. The specimen is bisected and submitted in cassette "I1," two pieces. Dictated by

CASSETTE SUMMARY:

D1FS:	Bronchial margin, shave
D2:	Vascular margin, shave
D3:	Lymph node, bisected
D4:	Five lymph nodes, whole
D5:	Representative section of normal inferior lobe
D6:	Tumor in relationship to bronchus and vessel
D7:	Tumor in relationship to pleura
D8:	Tumor in relation to normal lung
D9:	Mucinous area of lung
D10:	Representative section of superior lobe of left lung
E1-E3:	One node in each cassette, bisected
E4:	One node intact along with remaining adipose tissue
F1-F4:	One lymph node in each cassette bisected
F5:	Four possible lymph nodes intact

Printed by:
Printed on:

Page 4 of 5
(Continued)

[page 5 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

G1,G2: Two possible lymph nodes in each cassette intact
G3: One possible node intact
H1-H3: Largest possible node serially sectioned
H4,H5: One possible node in each cassette bisected

Intraoperative Consult Diagnosis

A1FS: 4R LYMPH NODE (FROZEN SECTION): ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
Frozen section results were communicated to the surgical team and were repeated back by

B1FS: #7 LYMPH NODE (FROZEN SECTION): NEGATIVE FOR METASTATIC CARCINOMA (0/1).
Frozen section results were communicated to the surgical team and were repeated back by

C1FS: 4L LYMPH NODE (FROZEN SECTION): NEGATIVE FOR METASTATIC CARCINOMA (0/1).
Frozen section results were communicated to the surgical team and were repeated back by

D1FS: LEFT LUNG, BRONCHIAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by

Pathologist: .

Microscopic Description

Microscopic examination performed.

Page 5 of 5
(End of Report)

10/25/12

Source: NCI Genomic Data Commons file 4ee20468-f7cf-48cf-98c8-b6bffc090ea3 (TCGA-94-A4VJ.361F56F8-52D2-434D-97DE-57E9EB5B1B3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).